Gene-level copy-number profile of tumor specimen TCGA-59-A5PD-01A from TCGA case TCGA-59-A5PD, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 55.5 years (20,263 days).
Specimen TCGA-59-A5PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.2612e023-e918-4aac-9ca0-422c52efe0bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-59-A5PD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e223d4c2-ef6c-42c4-8f33-95d5158abf90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 4,186; copy number 2: 23,862; copy number 3: 15,546; copy number 4: 11,067; copy number 5: 1,914; copy number 6: 1,379; copy number 7: 849; copy number 8: 550; copy number 9: 340; copy number 10: 84; copy number 11: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-59-A5PD-01A-11D-A402-01): tumor purity 0.67, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:89,581,209–91,612,566, 26 genes: LINC02161, AC113167.1, MIR3660, LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,081 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,098,809–27,490,167, 20 genes, copy number 7 (within-gene range 3–7): SLC9A1, AL590640.2, CHCHD3P3, NPM1P39, SNRPEP7, AL590640.1, WDTC1, Y_RNA, FO393419.3, TMEM222, RNU6-48P, ACTG1P20, SYTL1, MAP3K6, FCN3, CD164L2, FO393419.1, GPR3, WASF2, FO393419.2.
- chr1:28,505,943–29,326,813, 35 genes, copy number 5: RCC1, SNHG3, SNORA73A, SNORA73B, PRDX3P2, AL513497.1, TRNAU1AP, SNHG12, SNORD99, SNORA61, SNORA44, SNORA16A, SNORA16A, TAF12, RAB42, LINC01715, AL360012.1, RNU11, GMEB1, AL645729.1, YTHDF2, OPRD1, AL009181.1, Y_RNA, EPB41, AL138785.1, Y_RNA, Metazoa_SRP, TMEM200B, AL357500.1, SRSF4, AL357500.2, MECR, AL590729.1, PTPRU.
- chr1:183,248,237–183,418,380, 4 genes, copy number 6 (within-gene range 4–6): NMNAT2, AL354953.1, RPS3AP8, AL449223.1.
- chr1:186,176,814–203,744,081, 255 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:228,555,793–248,024,276, 436 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–24,919,839, 376 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:25,994,794–38,741,237, 248 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:181,690,380–194,761,435, 149 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:210,431,249–211,299,189, 5 genes, copy number 6 (within-gene range 4–6): LANCL1, CPS1, CPS1-IT1, AC012491.1, RPS27P10.
- chr2:211,535,653–211,535,769, 1 gene, copy number 6: RNA5SP119.
- chr3:145,523,538–198,222,513, 933 genes, copy number 6–11 (broad region; genes not listed).
- chr4:41,748,293–41,824,119, 1 gene, copy number 5 (within-gene range 2–5): PHOX2B-AS1.
- chr4:41,842,154–48,134,250, 74 genes, copy number 5 (broad region; genes not listed).
- chr4:48,153,434–48,153,535, 1 gene, copy number 5: Y_RNA.
- chr4:55,031,965–55,636,698, 21 genes, copy number 5 (within-gene range 4–5): RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU.
- chr4:153,307,792–153,415,118, 3 genes, copy number 6: ANXA2P1, MND1, RN7SL419P.
- chr5:58,198–31,595,669, 465 genes, copy number 8–10 (broad region; genes not listed).
- chr5:31,657,218–31,754,656, 7 genes, copy number 9: AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6.
- chr6:2,437,549–18,468,870, 292 genes, copy number 6 (broad region; genes not listed).
- chr6:18,571,784–18,571,880, 1 gene, copy number 6: MIR548A1.
- chr6:35,776,594–42,194,956, 156 genes, copy number 5–6 (broad region; genes not listed).
- chr7:41,667,168–41,705,834, 1 gene, copy number 7: INHBA.
- chr7:90,119,299–96,110,322, 103 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:91,909,738–145,066,685, 864 genes, copy number 5–9 (broad region; genes not listed).
- chr10:129,835,233–129,973,053, 1 gene, copy number 5 (within-gene range 4–5): EBF3.
- chr10:130,020,025–133,761,125, 92 genes, copy number 5 (broad region; genes not listed).
- chr11:13,784,017–13,924,863, 5 genes, copy number 5 (within-gene range 2–5): LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683.
- chr13:102,880,099–114,337,626, 170 genes, copy number 5–6 (broad region; genes not listed).
- chr20:87,250–11,029,455, 250 genes, copy number 5 (broad region; genes not listed).
- chr20:51,831,797–58,367,507, 104 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:37,550,026–37,666,932, 8 genes, copy number 5 (within-gene range 3–5): AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT.

Autosomal genes at a single copy (total copy number 1): 4,062. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
